CPTAC case C3L-10231 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/59d7aa38-0bd3-4ac4-91ad-1c5811e644cd

Demographics
Sex at birth: male; Race: white; Year of birth: 1943; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Body of stomach; Age at diagnosis: 79.9 years (29,177 days); Year of diagnosis: 2022; AJCC staging edition: 8th; AJCC pathologic T: T4a; AJCC pathologic N: N1; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Residual disease: R1; Days to last known disease status: 836 days (2.3 years); Progression or recurrence: yes; Days to recurrence: 651 days (1.8 years); Days to last follow up: 836 days (2.3 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 14 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 24.

Follow-up (1 entry)
- Days to follow up: 391 days (1.1 years); Disease response: Complete Response; Karnofsky performance status: 60; ECOG performance status: 2.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 90; Cigarettes per day: 40; Tobacco smoking onset year: 1968; Tobacco smoking quit year: 2013; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 45.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-10231-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 47 days; Initial weight: 237.2 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-10231-23: Section location: Body; Percent tumor nuclei: 15; Percent necrosis: 0.
- Sample C3L-10231-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 47 days; Method of sample procurement: Blood Draw.
